Somatic mutation profile of tumor specimen ALCH-AEKB-TTP1-A (aliquot ALCH-AEKB-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEKB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,806 days).
Specimen ALCH-AEKB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 535d6660-a04d-4e01-bf32-8380a8c0f0b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKB-NB1-A (Blood Derived Normal), aliquot ALCH-AEKB-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd01eb9e-df09-4348-b719-89ccc40a8172

The open-access MAF lists 91 somatic variants for this specimen: 70 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 11, Nonsense Mutation 5, Splice Site 3, RNA 3, Intron 3, In Frame Del 3, 5'Flank 2, Frame Shift Del 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHP4 | c.3325C>T p.R1109* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as rs758275952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV61275402; called by muse, mutect2, varscan2
- BAP1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs1440561167, COSV56243109; ClinVar: uncertain significance; called by muse, mutect2
- BTNL3 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 158/526 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1261658398; called by muse, mutect2, varscan2
- CD69 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1282100243; called by muse, mutect2, varscan2
- CLEC4D | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs779492386, COSV55230623; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 17/72 reads (24%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- DSP | c.8020G>T p.A2674S | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60939096; called by muse, mutect2, varscan2
- FGFR1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as rs1563627828; called by muse, mutect2
- HGH1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 48/415 reads (12%) | catalogued as rs1190716589; called by muse, mutect2, varscan2
- IGHV6-1 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs782001344; called by muse, mutect2, varscan2
- ITIH3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1171893686, COSV101407173; called by muse, mutect2, varscan2
- KRTAP5-11 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV59367436; called by muse, mutect2
- MYO15A | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.094); catalogued as rs1020096056; called by muse, mutect2
- NF1 | c.6705-2A>T p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 50/538 reads (9%) | catalogued as CS1413893, COSV100647415; called by muse, mutect2
- NRXN1 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV68002117, COSV68014469; called by muse, mutect2, varscan2
- PCDHA2 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100973709, COSV65365365; called by muse, mutect2
- RGS4 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV63357779; called by muse, mutect2
- SSX3 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 71/519 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs1556950427; called by muse, mutect2, varscan2
- SUPT5H | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63239314; called by muse, mutect2, varscan2
- SYT9 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs374567594; called by muse, mutect2, varscan2
- TAF3 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 76/409 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as rs370043528; called by muse, mutect2, varscan2
- ZFAT | c.2425A>G p.T809A | Missense Mutation (SNP) | VAF 77/593 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.583); catalogued as COSV100914546; called by muse, mutect2, varscan2
- ZFHX4 | c.3106C>A p.Q1036K | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV50482153; called by muse, mutect2
- ZNF280C | c.653T>C p.M218T | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs369995712; called by muse, mutect2, varscan2
- ZNF318 | c.6638C>T p.S2213L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs767844232, COSV100545916; called by muse, mutect2, varscan2
- ADTRP | c.592T>C p.S198P | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ANKFN1 | c.3013_3017del p.N1005Yfs*26 (on ENST00000653862; = p.N858Yfs*26 on NM_001365758.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 95/486 reads (20%) | called by mutect2, pindel, varscan2
- ANKS1B | c.2877C>G p.I959M (on ENST00000547776 / NM_152788.4; = p.I185M on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ATAT1 | c.1181C>T p.A394V (on ENST00000376485; = p.A382V on NM_001031722.4) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); called by mutect2, varscan2
- C11orf71 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- CMTR2 | c.1068T>A p.F356L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DACH2 | c.1150A>G p.N384D | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHRS11 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- DIPK1C | c.806G>C p.S269T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DMD | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- DPP3 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ERC2 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FRAS1 | c.8850G>C p.E2950D | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- GNPAT | c.1937+2dup p.X646_splice | Splice Site (INS) | VAF 104/695 reads (15%) | called by mutect2, pindel, varscan2
- HDC | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- HLA-G | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- IFFO2 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- IFT27 | c.113T>C p.L38P (on ENST00000433985 / NM_001363003.2; = p.L37P on NM_006860.5) | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- INO80D | c.1463C>A p.A488E | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- IREB2 | c.2258A>G p.D753G | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2
- KANK1 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- KLHL32 | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KPTN | c.869_892del p.L290_D297del | In Frame Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- KRTAP8-1 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- LOXHD1 | c.1897T>A p.W633R | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY75 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAML2 | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 97/905 reads (11%) | called by muse, varscan2
- MDFI | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); called by muse, mutect2
- NBAS | c.5137G>T p.G1713C | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NF1 | c.2595_2605del p.P866Sfs*3 | Frame Shift Del (DEL) | VAF 89/578 reads (15%) | called by mutect2, pindel, varscan2
- NSRP1 | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OPHN1 | c.500T>A p.V167E | Missense Mutation (SNP) | VAF 47/518 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- PAMR1 | c.1321T>C p.S441P (on ENST00000619888 / NM_001001991.3; = p.S458P on NM_015430.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PKHD1 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 44/625 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- POGLUT1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 72/461 reads (16%) | called by muse, mutect2, varscan2
- PPFIA3 | c.2581_2589del p.C861_A863del | In Frame Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- PPT2 | c.338-6_342del p.X113_splice | Splice Site (DEL) | VAF 23/237 reads (10%) | called by mutect2, pindel
- PRMT9 | c.875A>T p.K292M | Missense Mutation (SNP) | VAF 25/611 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2
- RP9 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 55/659 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK3 | c.2467T>C p.S823P | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); called by muse, mutect2
- SPTLC1 | c.1308G>C p.E436D | Missense Mutation (SNP) | VAF 62/676 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- STAG2 | c.2447C>A p.T816N | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- TMPPE | c.990C>G p.C330W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNFRSF11B | c.1053C>G p.H351Q | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AHNAK2 | c.16389C>A p.V5463= | Silent (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- DST | c.9198T>C p.R3066= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- GPR78 | c.1032G>A p.A344= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs774004850; called by muse, mutect2
- IL25 | c.273A>G p.R91= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- KRT73 | c.1027C>T p.L343= | Silent (SNP) | VAF 31/352 reads (9%) | catalogued as rs144353604, COSV59839515; called by muse, mutect2
- LCT | c.4438C>T p.L1480= | Silent (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- NKAPL | c.270G>A p.S90= | Silent (SNP) | VAF 19/213 reads (9%) | catalogued as COSV59197436; called by muse, mutect2
- PIGA | c.144C>T p.G48= | Silent (SNP) | VAF 28/396 reads (7%) | called by muse, mutect2
- RWDD3 | c.480G>A p.E160= | Silent (SNP) | VAF 43/294 reads (15%) | catalogued as COSV55722335; called by muse, mutect2, varscan2
- SLC30A6 | c.606T>A p.V202= | Silent (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- TTN | c.37602C>T p.F12534= (on ENST00000591111; = p.F5110= on NM_003319.4) | Silent (SNP) | VAF 51/472 reads (11%) | catalogued as rs769204115; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148213 C>G | 5'Flank (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- EIF4G3 | c.-141C>T | 5'UTR (SNP) | VAF 52/359 reads (14%) | called by muse, mutect2, varscan2
- FBXL18 | c.2000+1144G>T | Intron (SNP) | VAF 48/275 reads (17%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.783A>C | RNA (SNP) | VAF 40/454 reads (9%) | called by muse, mutect2
- LINC02210-CRHR1 | c.-493+11336_-493+11337del | Intron (DEL) | VAF 26/124 reads (21%) | catalogued as rs1302313115; called by mutect2, pindel
- LINC02551 | n.1332C>T | RNA (SNP) | VAF 20/564 reads (4%) | called by muse, mutect2
- MIR7-3 | chr19:4769660 G>T | 5'Flank (SNP) | VAF 18/136 reads (13%) | catalogued as rs1367087799; called by muse, mutect2, varscan2
- PEG10 | c.*996C>T | 3'UTR (SNP) | VAF 33/240 reads (14%) | catalogued as COSV101510006; called by muse, mutect2, varscan2
- PSMC3IP | c.337+34G>A | Intron (SNP) | VAF 189/737 reads (26%) | catalogued as rs1233869912; called by muse, mutect2, varscan2
- ZNF890P | n.693C>G | RNA (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
